Somatic mutation profile of tumor specimen TCGA-97-8552-01A (aliquot TCGA-97-8552-01A-11D-2393-08) from TCGA case TCGA-97-8552, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 55.7 years (20,331 days).
Specimen TCGA-97-8552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c534284e-9bde-42ff-87c3-effe204a4030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8552-10A (Blood Derived Normal), aliquot TCGA-97-8552-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22bafb55-4327-4fbc-8443-0587fb49d8fd

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 16/92 reads (17%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- PIK3CA | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as COSV55918383, COSV55932743, COSV55991103; called by muse, mutect2, varscan2
- ACTR8 | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs748405850, COSV99213596; called by muse, mutect2, varscan2
- ANK3 | c.4976C>T p.P1659L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV99778563; called by muse, mutect2, varscan2
- ATRX | c.4540C>T p.R1514* | Nonsense Mutation (SNP) | VAF 32/223 reads (14%) | catalogued as COSV64871896; called by muse, mutect2, varscan2
- CCDC136 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.337); catalogued as COSV99922234, COSV99922247; called by muse, mutect2, varscan2
- CLIC6 | c.1453G>A p.G485R (on ENST00000360731 / NM_001317009.2; = p.G467R on NM_053277.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868729882, COSV62449513; called by muse, mutect2, varscan2
- CNTN3 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99723455; called by mutect2, varscan2
- DDHD2 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101240444, COSV101240525; called by muse, mutect2, varscan2
- FAM120A | c.200G>C p.S67T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99464643; called by muse, mutect2
- FBN1 | c.4768C>T p.P1590S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100354124; called by muse, mutect2, varscan2
- FGL2 | c.1112G>C p.C371S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191569909, COSV99592233; called by muse, mutect2, varscan2
- KIFC1 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100997079, COSV65737545; called by muse, mutect2, varscan2
- RAD17 | c.1879G>T p.E627* (on ENST00000380774 / NM_133339.2; = p.E616* on NM_002873.1) | Nonsense Mutation (SNP) | VAF 25/170 reads (15%) | catalogued as COSV99281196; called by muse, mutect2, varscan2
- SFTPC | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100109154, COSV100110239; called by muse, mutect2, varscan2
- SPATA18 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs745462753, COSV54649291; called by muse, mutect2, varscan2
- SPTB | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as rs1285270460, COSV101071990; called by muse, mutect2
- TRPM2 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442450675, COSV100308268; called by muse, mutect2, varscan2
- ZNF433 | c.1558T>G p.S520A | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs1034527308, COSV100794948; called by muse, mutect2, varscan2
- ZNF468 | c.499T>A p.S167T | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99700376; called by muse, mutect2, varscan2
- ZNF770 | c.250_264del p.S84_R88del | In Frame Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- CHRNA1 | c.657G>T p.G219= (on ENST00000261007 / NM_001039523.3; = p.G194= on NM_000079.4) | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99650201; called by muse, varscan2
- PTPRB | c.3996C>G p.V1332= | Silent (SNP) | VAF 40/231 reads (17%) | catalogued as rs1441006649, COSV99716119; called by muse, mutect2, varscan2
- TNN | c.3558G>A p.R1186= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99511231; called by muse, mutect2, varscan2
- XAB2 | c.1206C>G p.A402= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100601512; called by muse, mutect2, varscan2
